Gene-level copy-number profile of tumor specimen TCGA-ZF-AA56-01A from TCGA case TCGA-ZF-AA56, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 79.2 years (28,937 days).
Specimen TCGA-ZF-AA56-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.cb3a0316-016d-4f24-97f1-96b1b4f7abc2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZF-AA56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1ac42938-31a2-4bf0-be95-f3a89ee0c8db

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 74; copy number 1: 1,441; copy number 2: 8,173; copy number 3: 35,151; copy number 4: 10,546; copy number 5: 2,952; copy number 6: 634; copy number 7: 493; copy number 8: 243; copy number 9: 14; copy number 11: 90.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZF-AA56-01A-31D-A390-01): tumor purity 0.28, ploidy 3.22, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,341,669–22,824,213, 65 genes (within-gene range 0–2) (broad region; genes not listed).
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 840 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–94,507,620, 11 genes, copy number 7: RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1.
- chr3:96,814,581–104,063,582, 114 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr3:148,695,994–175,810,548, 401 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr3:175,609,479–178,172,449, 33 genes, copy number 7: RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1, LINC01208, MIR7977, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC110992.1.
- chr3:178,419,123–178,843,300, 1 gene, copy number 7 (within-gene range 2–7): AC117457.1.
- chr3:178,526,505–180,476,778, 34 genes, copy number 7 (within-gene range 2–7): KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1, ZNF639, AC007823.1, MFN1, GNB4, AC007620.2, AC007620.3, AC007620.1, MTHFD2P7, ACTL6A, AC090425.3, AC090425.2, MRPL47, NDUFB5, AC090425.1, H3P13, USP13, PEX5L, AC007687.1, PEX5L-AS1, PEX5L-AS2, AC092939.1, RNA5SP149, AC134503.1, GAPDHP36, RALBP1P1, LINC02053.
- chr5:5,688,805–10,676,423, 120 genes, copy number 8 (broad region; genes not listed).
- chr13:73,227,147–73,408,352, 3 genes, copy number 7: RNY1P8, AL162376.1, MARK2P12.
- chr17:30,238,741–32,491,253, 116 genes, copy number 8 (broad region; genes not listed).
- chr17:32,495,536–32,531,492, 7 genes, copy number 8: AC079336.5, AC079336.7, AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3.

Autosomal genes at a single copy (total copy number 1): 954. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
